Somatic mutation profile of tumor specimen C3L-02654-02 (aliquot CPT0205140006) from CPTAC case C3L-02654, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 70.6 years (25,783 days).
Specimen C3L-02654-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 598e475f-f454-47c6-8168-48ce625d5726.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02654-31 (Blood Derived Normal), aliquot CPT0205290002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d608b203-9b68-4ce2-8c92-0e4c79e4deae

The open-access MAF lists 83 somatic variants for this specimen: 47 protein-altering or splice-affecting, 21 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 21, Intron 7, RNA 5, Nonsense Mutation 4, 5'UTR 2, 3'UTR 1, In Frame Del 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 3065/3488 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 134/313 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC2 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 70/324 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.724); catalogued as rs370287805; called by muse, mutect2, varscan2
- ENOSF1 | c.797+3G>T | Splice Region (SNP) | VAF 94/283 reads (33%) | catalogued as COSV99201125; called by muse, mutect2, varscan2
- ERICH3 | c.3757G>C p.G1253R | Missense Mutation (SNP) | VAF 80/344 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100443816; called by muse, mutect2, varscan2
- FAM47C | c.2627C>T p.P876L | Missense Mutation (SNP) | VAF 31/417 reads (7%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.546); catalogued as rs782528684, COSV100792346; called by muse, mutect2
- FDXR | c.899C>A p.S300Y (on ENST00000293195 / NM_024417.5; = p.S306Y on NM_004110.6) | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as COSV53117868; called by muse, mutect2, varscan2
- FLG | c.5342G>A p.R1781H | Missense Mutation (SNP) | VAF 101/785 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs144863102; called by muse, mutect2, varscan2
- GRIN3A | c.3084C>G p.I1028M | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV62450484; called by muse, mutect2, varscan2
- JAG2 | c.2693G>A p.R898H | Missense Mutation (SNP) | VAF 108/371 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs754481519; called by muse, mutect2, varscan2
- LRRC6 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 96/291 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as rs1269967708; called by muse, mutect2, varscan2
- NUP210 | c.398C>G p.S133C | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV54404653; called by muse, mutect2, varscan2
- PTPRZ1 | c.4307G>T p.G1436V | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.499); catalogued as rs375424431; called by muse, mutect2, varscan2
- PTPRZ1 | c.6925G>T p.E2309* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as COSV99081120; called by muse, mutect2, varscan2
- RALGAPB | c.4219C>G p.Q1407E | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV53434117; called by muse, mutect2, varscan2
- SDK2 | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs374727187; called by muse, mutect2, varscan2
- SI | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0.023); catalogued as COSV52267434; called by muse, mutect2, varscan2
- SLCO1A2 | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV56602152; called by muse, mutect2, varscan2
- SUGP2 | c.655G>A p.V219I | Missense Mutation (SNP) | VAF 17/191 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs570581228; called by muse, mutect2
- TAF1 | c.4389G>C p.E1463D (on ENST00000373790 / NM_138923.4; = p.E1484D on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.413); catalogued as COSV52118791; called by muse, mutect2, varscan2
- THSD7B | c.3655G>A p.G1219S (on ENST00000272643; = p.G1217S on NM_001316349.2) | Missense Mutation (SNP) | VAF 34/175 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); catalogued as rs375133517; called by muse, mutect2, varscan2
- AKR1C2 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 33/285 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- ARHGEF37 | c.523T>C p.Y175H | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATF6B | c.331C>G p.P111A | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.036); called by muse, mutect2
- BMS1 | c.1133C>G p.S378C | Missense Mutation (SNP) | VAF 40/253 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); called by muse, varscan2
- BMS1 | c.1208C>G p.S403* | Nonsense Mutation (SNP) | VAF 26/235 reads (11%) | called by muse, varscan2
- C2orf42 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- C8orf34 | c.999_1001del p.L334del | In Frame Del (DEL) | VAF 18/180 reads (10%) | called by mutect2, pindel, varscan2
- DST | c.18250G>C p.V6084L (on ENST00000361203 / NM_001374722.1; = p.V3781L on NM_015548.5) | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.279); called by muse, mutect2
- GCN1 | c.4179G>T p.E1393D | Missense Mutation (SNP) | VAF 53/565 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.804); called by muse, mutect2
- GPR82 | c.686G>C p.R229T | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- H3C2 | c.136A>G p.T46A | Missense Mutation (SNP) | VAF 91/644 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- HSD17B8 | c.46G>T p.V16F | Missense Mutation (SNP) | VAF 91/367 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEE1 | c.2080G>T p.D694Y | Missense Mutation (SNP) | VAF 53/400 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- MAP3K1 | c.958C>T p.Q320* | Nonsense Mutation (SNP) | VAF 100/429 reads (23%) | called by muse, mutect2, varscan2
- METTL22 | c.243G>C p.E81D | Missense Mutation (SNP) | VAF 77/362 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYEF2 | c.1154G>T p.G385V | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYH2 | c.3026A>T p.H1009L | Missense Mutation (SNP) | VAF 105/494 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- NFXL1 | c.1903G>T p.V635F | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); called by muse, mutect2
- NRK | c.3418C>T p.Q1140* | Nonsense Mutation (SNP) | VAF 9/192 reads (5%) | called by muse, mutect2
- PTPRB | c.131A>G p.Q44R | Missense Mutation (SNP) | VAF 82/273 reads (30%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PTPRF | c.661G>C p.A221P | Missense Mutation (SNP) | VAF 58/305 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STYXL2 | c.2899C>G p.L967V | Missense Mutation (SNP) | VAF 18/499 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- TPTE | c.833A>T p.H278L (on ENST00000618007 / NM_199261.4; = p.H260L on NM_199259.4) | Missense Mutation (SNP) | VAF 29/217 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- ZNF527 | c.958_971del p.H320Yfs*7 | Frame Shift Del (DEL) | VAF 153/218 reads (70%) | called by mutect2, pindel*, varscan2*
- ZNF718 | c.990G>C p.K330N | Missense Mutation (SNP) | VAF 35/371 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.065); called by muse, mutect2
- ZNF718 | c.1118G>A p.G373E | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- BRAF | c.2184C>T p.A728= (on ENST00000288602 / NM_001374244.1; = p.A688= on NM_004333.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 10/267 reads (4%) | catalogued as rs1554389847; ClinVar: likely benign; called by muse, mutect2
- BTNL3 | c.123C>T p.S41= | Silent (SNP) | VAF 72/184 reads (39%) | called by muse, mutect2, varscan2
- CCDC158 | c.1182T>C p.S394= | Silent (SNP) | VAF 82/267 reads (31%) | called by muse, mutect2, varscan2
- CHD4 | c.4689C>T p.S1563= (on ENST00000357008 / NM_001363606.2; = p.S1576= on NM_001273.5) | Silent (SNP) | VAF 77/316 reads (24%) | called by muse, mutect2, varscan2
- DOCK4 | c.5196G>A p.E1732= | Silent (SNP) | VAF 33/215 reads (15%) | called by muse, mutect2, varscan2
- IGHE | c.1104C>T p.D368= | Silent (SNP) | VAF 171/517 reads (33%) | catalogued as rs782704173; called by muse, mutect2, varscan2
- ITIH5 | c.2319C>G p.L773= | Silent (SNP) | VAF 44/180 reads (24%) | called by muse, mutect2, varscan2
- KIF5C | c.201G>A p.A67= | Silent (SNP) | VAF 12/123 reads (10%) | catalogued as rs1469750079; called by muse, mutect2, varscan2
- KPRP | c.1110G>C p.L370= | Silent (SNP) | VAF 218/489 reads (45%) | catalogued as COSV100908694; called by muse, mutect2, varscan2
- KRTAP25-1 | c.234C>T p.F78= | Silent (SNP) | VAF 13/110 reads (12%) | called by muse, mutect2, varscan2
- MDGA2 | c.204G>A p.V68= | Silent (SNP) | VAF 46/468 reads (10%) | catalogued as rs1200411146; called by muse, mutect2
- ORC5 | c.1014C>A p.T338= | Silent (SNP) | VAF 29/138 reads (21%) | called by muse, mutect2, varscan2
- RAB3GAP1 | c.2817C>T p.F939= | Silent (SNP) | VAF 75/534 reads (14%) | catalogued as COSV51481319; called by muse, mutect2, varscan2
- RAI2 | c.819G>C p.L273= | Silent (SNP) | VAF 6/146 reads (4%) | called by muse, mutect2
- SATB1 | c.1440C>T p.A480= | Silent (SNP) | VAF 12/132 reads (9%) | called by muse, mutect2
- TEN1 | c.219C>T p.Y73= | Silent (SNP) | VAF 29/223 reads (13%) | called by muse, mutect2, varscan2
- TMEM268 | c.417G>A p.L139= | Silent (SNP) | VAF 26/187 reads (14%) | catalogued as rs925830089; called by muse, mutect2, varscan2
- TRGV2 | c.231G>A p.L77= | Silent (SNP) | VAF 120/500 reads (24%) | called by muse, varscan2
- TRGV2 | c.99T>G p.T33= | Silent (SNP) | VAF 108/416 reads (26%) | called by muse, varscan2
- ZFYVE28 | c.852G>A p.R284= | Silent (SNP) | VAF 80/326 reads (25%) | called by muse, mutect2, varscan2
- ZNF791 | c.1188T>C p.P396= | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as rs1481910175; called by muse, mutect2, varscan2
- ABLIM3 | c.335+667T>C | Intron (SNP) | VAF 50/238 reads (21%) | called by muse, mutect2
- AC020907.6 | c.-477G>A | 5'UTR (SNP) | VAF 363/531 reads (68%) | catalogued as rs750623528; called by muse, mutect2, varscan2
- CLEC4A | c.299-894C>G | Intron (SNP) | VAF 29/232 reads (13%) | called by muse, mutect2, varscan2
- DCHS2 | n.6755A>T | RNA (SNP) | VAF 23/173 reads (13%) | called by muse, mutect2, varscan2
- FAM193B | c.1076+40G>C | Intron (SNP) | VAF 40/300 reads (13%) | called by muse, mutect2, varscan2
- FRMPD2B | n.738T>C | RNA (SNP) | VAF 62/415 reads (15%) | called by muse, mutect2, varscan2
- HSP90AA4P | n.400T>G | RNA (SNP) | VAF 51/205 reads (25%) | catalogued as rs1359261330; called by muse, mutect2, varscan2
- LINC01100 | n.69G>C | RNA (SNP) | VAF 27/250 reads (11%) | called by muse, mutect2, varscan2
- LTBP1 | c.1034-339C>G | Intron (SNP) | VAF 16/324 reads (5%) | catalogued as rs1182714533, COSV63188132; called by muse, mutect2
- NTNG1 | c.1087+195A>C | Intron (SNP) | VAF 44/182 reads (24%) | catalogued as COSV53965810; called by muse, mutect2, varscan2
- PPDPFL | c.*701T>C | 3'UTR (SNP) | VAF 77/408 reads (19%) | catalogued as rs1180741188; called by muse, mutect2, varscan2
- PRMT2 | c.654+2151C>G | Intron (SNP) | VAF 297/540 reads (55%) | catalogued as rs561986019; called by muse, mutect2, varscan2
- RPS4XP21 | n.597C>T | RNA (SNP) | VAF 241/370 reads (65%) | called by muse, mutect2, varscan2
- TRPM2 | c.-15C>T | 5'UTR (SNP) | VAF 11/73 reads (15%) | catalogued as rs369007875; called by muse, mutect2, varscan2
- TSPAN7 | c.81+1433T>C | Intron (SNP) | VAF 27/147 reads (18%) | called by muse, mutect2, varscan2
